CCDI case PBCTPH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/5fe1d571-c4de-4f15-89e9-84bcdd714e9c

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Overlapping lesion of rectum, anus and anal canal; Age at diagnosis: 14.5 years (5,306 days).

Biospecimens (3 samples)
- Sample 0DZ39K: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DZ39V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DZ3A1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
